Gene-level copy-number profile of tumor specimen HCM-SANG-1081-C20-08A-01D-A80T-32 from HCMI case HCM-SANG-1081-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; Tumor grade: G2.
Specimen HCM-SANG-1081-C20-08A-01D-A80T-32: Sample type: Post neo-adjuvant therapy; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 87328002-3191-4853-92fc-e8c3e1d45da0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1081-C20-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/0e4dfc34-0902-4fcb-88b9-4da33842bac3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 3,903; copy number 2: 53,192; copy number 3: 1,311; copy number 4: 488; copy number 5: 2; copy number 6: 3; copy number 7: 4.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,632,568–2,801,717, 4 genes (within-gene range 0–2): MMEL1-AS1, TTC34, AC242022.2, AC242022.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,319,625–89,600,680, 3 genes, copy number 6: IGKV1-39, IGKV2-40, 5S_rRNA.
- chr8:145,047,860–145,066,685, 2 genes, copy number 5: AC139103.1, C8orf33.
- chr20:30,484,925–30,816,274, 4 genes, copy number 7: 5_8S_rRNA, ANKRD20A21P, U6, RNA5SP528.

Autosomal genes at a single copy (total copy number 1): 1,048. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
